Surgical pathology report (de-identified scan), TCGA case TCGA-4W-AA9T, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Miami, specimen TCGA-4W-AA9T-01A (Primary Tumor).

[page 1 of 2]
RUN DATE:
RUN TIME:

PAGE 1

*** FINAL REPORT ***
SURGICAL PATHOLOGY REPORT

PATIENT: [REDACTED]		ACCT #: [REDACTED]	
AGE/SEX: /F [REDACTED]	ROOM: [REDACTED]	REG: [REDACTED]	DIS: [REDACTED]
REG DR: [REDACTED]	STATUS: [REDACTED]	BED: [REDACTED]	DIS: [REDACTED]
Path #: [REDACTED]		Received: [REDACTED]	Collected: [REDACTED]
Submit Dr: [REDACTED]		Copies to: [REDACTED]	
SPECIMEN ID: A. BRAIN - BRAIN TUMOR FS, B. BRAIN - BRAIN TUMOR *** FINAL DIAGNOSIS *** A. BRAIN TUMOR: GLIOBLASTOMA, (WHO grade IV of IV). B. BRAIN TUMOR: GLIOBLASTOMA, (WHO grade IV of IV). Dictated by: [REDACTED]			
CLINICAL HISTORY- PRE-OP DX: Not provided PROCEDURE: Craniotomy RELEVANT CLINICAL HX: Brain mass - frontal			
GROSS DESCRIPTION: A. Received fresh and labeled "Brain tumor" are multiple, light-tan, irregularly-shaped soft tissue fragment measuring 1.0 x 0.8 x 0.3 cm. The specimen is submitted in toto in one cassette for frozen section. B. Received in formalin and labeled "Brain tumor" are two light-tan, irregularly-shaped soft tissue fragments measuring 1.5 x 0.5 x 0.5 cm in aggregate. The specimen is submitted in toto in one cassette.			
This report is privileged, confidential and exempt from disclosure under applicable law. If you receive this report inadvertently, please call [REDACTED] and return the report to us by mail.			

ICD O-3
Glioblastoma multiforme
944013
Site Brain NOS
071.9
JAD 3/11/14

[page 2 of 2]
RUN DATE:
RUN TIME:

*** FINAL REPORT ***
SURGICAL PATHOLOGY REPORT

PAGE 2

SPEC #:	[REDACTED]	(Continued)
GROSS DESCRIPTION: (Continued)		
OPERATING ROOM CONSULT (FS-CYT)		
AFS. BRAIN TUMOR		
Glioblastoma.		
[REDACTED]		
Dictated by: [REDACTED]		
Signed (Signature on file) [REDACTED]		

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

Crit-ria	12/18/13	Yes	No
Dual/Synchronous Primary	Noted		/

Source: NCI Genomic Data Commons file 2271329b-6514-4bb9-b653-b3c26d8a82bb (TCGA-4W-AA9T.F1D9DB81-6170-4A62-B16E-0D826CD0D173.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).